Somatic mutation profile of tumor specimen TCGA-D8-A1XV-01A (aliquot TCGA-D8-A1XV-01A-11D-A14K-09) from TCGA case TCGA-D8-A1XV, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 84.4 years (30,830 days).
Specimen TCGA-D8-A1XV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8920e3cb-5a6f-42b9-bbe7-6d9298aaf395.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D8-A1XV-10A (Blood Derived Normal), aliquot TCGA-D8-A1XV-10A-01D-A14K-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ceba3c10-8dab-489b-a84f-db4661fa6c34

The open-access MAF lists 31 somatic variants for this specimen: 21 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 9, RNA 1, Nonsense Mutation 1, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC004922.1 | c.875G>A p.S292N | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0.255); catalogued as COSV53557749; called by muse, mutect2
- ATP13A1 | c.1030C>G p.R344G | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as rs371113170, COSV52285212; called by muse, mutect2, varscan2
- CAVIN1 | c.104C>T p.P35L | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV63811770; called by muse, mutect2, varscan2
- CCDC17 | c.698C>T p.P233L | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as rs987920344, COSV51969023; called by muse, mutect2, varscan2
- CEACAM16 | c.925G>A p.V309M | Missense Mutation (SNP) | VAF 56/139 reads (40%) | SIFT tolerated (0.29); PolyPhen benign (0.26); catalogued as rs545264324, COSV69186656; called by muse, mutect2, varscan2
- CYP1A2 | c.1447G>A p.V483M | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.876); catalogued as rs143028942; called by muse, mutect2, varscan2
- DDX6 | c.1198A>T p.I400L | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV50588454; called by muse, mutect2, varscan2
- FOXA1 | c.1235del p.Q412Rfs*28 | Frame Shift Del (DEL) | VAF 60/157 reads (38%) | catalogued as COSV51645518; called by mutect2, pindel, varscan2
- HOMER1 | c.967C>T p.R323C | Missense Mutation (SNP) | VAF 30/150 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs781650763, COSV56524093; called by muse, mutect2, varscan2
- HPSE | c.843-1G>T p.X281_splice | Splice Site (SNP) | VAF 47/115 reads (41%) | catalogued as COSV60986608; called by muse, mutect2, varscan2
- INO80C | c.575C>T p.P192L | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.351); catalogued as COSV58047326; called by muse, mutect2, varscan2
- KIF18B | c.973A>T p.I325F | Missense Mutation (SNP) | VAF 91/183 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59272729; called by muse, mutect2, varscan2
- MGAT4B | c.1055G>A p.R352Q | Missense Mutation (SNP) | VAF 48/118 reads (41%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.695); catalogued as rs1163145003, COSV52977679; called by muse, mutect2, varscan2
- MTMR6 | c.1619G>A p.R540H | Missense Mutation (SNP) | VAF 91/217 reads (42%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs772892485, COSV67808264, COSV67808542; called by muse, mutect2, varscan2
- ODF2L | c.773G>T p.G258V | Missense Mutation (SNP) | VAF 81/178 reads (46%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.745); catalogued as COSV54015237; called by muse, mutect2, varscan2
- PCDHGA3 | c.2086G>C p.A696P | Missense Mutation (SNP) | VAF 59/150 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); catalogued as COSV53937212; called by muse, mutect2, varscan2
- PHF3 | c.5270G>T p.G1757V | Missense Mutation (SNP) | VAF 40/81 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV100013136; called by muse, mutect2, varscan2
- REST | c.778G>T p.E260* | Nonsense Mutation (SNP) | VAF 23/77 reads (30%) | catalogued as COSV100470943, COSV58360407; called by muse, mutect2, varscan2
- TNFRSF6B | c.137G>A p.R46Q | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as rs572993898, COSV53927347; called by muse, mutect2, varscan2
- ZNF689 | c.644C>T p.S215F | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs779342836, COSV54908431; called by muse, mutect2, varscan2
- ZNF710 | c.1725C>G p.F575L | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV99184113; called by muse, mutect2, varscan2
- CD177 | c.648C>A p.T216= | Silent (SNP) | VAF 45/101 reads (45%) | catalogued as COSV100945905; called by muse, mutect2, varscan2
- CD200R1L | c.588T>C p.S196= | Silent (SNP) | VAF 28/93 reads (30%) | catalogued as rs1407919881, COSV68004173; called by muse, mutect2, varscan2
- CLPX | c.375C>G p.V125= | Silent (SNP) | VAF 70/157 reads (45%) | catalogued as COSV100269531, COSV55644260; called by muse, mutect2, varscan2
- FAM126A | c.1398G>A p.P466= | Silent (SNP) | VAF 10/81 reads (12%) | catalogued as rs752544627, COSV69471164; called by muse, mutect2, varscan2
- FFAR3 | c.153C>T p.D51= | Silent (SNP) | VAF 111/349 reads (32%) | catalogued as rs372231935, COSV59908989; called by muse, varscan2
- GOLGB1 | c.2964T>C p.N988= | Silent (SNP) | VAF 17/72 reads (24%) | catalogued as COSV61465284; called by muse, mutect2, varscan2
- IGSF8 | c.1695A>G p.S565= | Silent (SNP) | VAF 21/95 reads (22%) | catalogued as COSV58757872; called by muse, mutect2, varscan2
- PSMA8 | c.45C>T p.D15= | Silent (SNP) | VAF 31/65 reads (48%) | catalogued as rs1475300466, COSV57602160; called by muse, mutect2, varscan2
- PSMB11 | c.309C>T p.T103= | Silent (SNP) | VAF 8/98 reads (8%) | catalogued as COSV101273430; called by muse, mutect2
- C1orf220 | n.726C>G | RNA (SNP) | VAF 41/192 reads (21%) | called by muse, mutect2, varscan2
